Somatic mutation profile of tumor specimen TCGA-QK-A6IG-01A (aliquot TCGA-QK-A6IG-01A-11D-A31L-08) from TCGA case TCGA-QK-A6IG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.4 years (25,334 days).
Specimen TCGA-QK-A6IG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0588c361-a204-4ce7-926c-40702373204e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A6IG-10A (Blood Derived Normal), aliquot TCGA-QK-A6IG-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8ba0fd3-0c96-437b-8c61-dbac3cbfda0d

The open-access MAF lists 127 somatic variants for this specimen: 101 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 23, Nonsense Mutation 15, Intron 2, Splice Region 1, 3'Flank 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 22/34 reads (65%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL12A1 | c.3310C>T p.R1104* | Nonsense Mutation (SNP) | VAF 22/175 reads (13%) | catalogued as rs1329022055, COSV100485675; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.5477G>A p.R1826H (on ENST00000333535 / NM_198056.3; = p.R1825H on NM_000335.5) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs137854610, CM014389; ClinVar: uncertain significance / pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 43/61 reads (70%) | hotspot (GDC flag); catalogued as CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; called by muse, mutect2, varscan2
- AC006059.2 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); catalogued as rs1436017127, COSV100045795, COSV59605627; called by muse, mutect2
- ADAM20 | c.1382C>G p.S461* | Nonsense Mutation (SNP) | VAF 23/147 reads (16%) | catalogued as COSV99833376; called by muse, mutect2, varscan2
- ADAMTS3 | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV54384393, COSV99710646; called by muse, mutect2, varscan2
- ADGRV1 | c.10642G>A p.A3548T | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV101315690; called by muse, mutect2, varscan2
- AHNAK2 | c.9011C>G p.S3004C | Missense Mutation (SNP) | VAF 97/558 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV100316629; called by muse, mutect2, varscan2
- AKAP9 | c.5758G>C p.E1920Q (on ENST00000359028; = p.E1888Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV100662170; called by muse, mutect2, varscan2
- ANK3 | c.12542C>G p.S4181* (on ENST00000280772 / NM_001320874.2; = p.S702* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99779131; called by muse, mutect2, varscan2
- ARHGAP19 | c.1174C>T p.L392F | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100363064; called by muse, mutect2, varscan2
- ARHGAP39 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.15); catalogued as COSV52766543, COSV99431327; called by muse, mutect2, varscan2
- ARHGEF4 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100387830; called by muse, mutect2, varscan2
- ARL5B | c.434G>C p.S145T | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV101040267; called by muse, mutect2
- ASB4 | c.1123A>T p.T375S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100367137; called by muse, mutect2, varscan2
- BBS10 | c.664A>C p.N222H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV99674755; called by muse, mutect2, varscan2
- BTN2A2 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.216); catalogued as COSV100760312; called by muse, mutect2, varscan2
- CACNA1G | c.4801C>T p.R1601W | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751861938, COSV61737415; called by muse, mutect2, varscan2
- CAD | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs368446772; called by muse, mutect2, varscan2
- CALHM2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as rs777219053, COSV99588370; called by muse, mutect2, varscan2
- CARS1 | c.2234G>C p.G745A | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs932188188, COSV99542342, COSV99543473; called by muse, mutect2, varscan2
- CASP8 | c.1303C>T p.R435* (on ENST00000432109 / NM_033355.3; = p.R452* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as rs1368296717, COSV51844657; called by muse, mutect2, varscan2
- CAT | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs771814610, COSV99573157; called by muse, mutect2, varscan2
- CD300C | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs141778260; called by muse, varscan2
- CEL | c.1541A>G p.Y514C (on ENST00000673714; = p.Y511C on NM_001807.6) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100672354; called by muse, mutect2, varscan2
- CEP78 | c.1552G>C p.E518Q (on ENST00000424347 / NM_001349840.2; = p.E519Q on NM_032171.3) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99450152; called by muse, mutect2, varscan2
- CRYGS | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs967876042, COSV100329945; called by muse, mutect2, varscan2
- DAZAP2 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as COSV101331557; called by muse, mutect2, varscan2
- DCC | c.2367T>G p.S789R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100499019; called by muse, mutect2, varscan2
- DGCR8 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100707876; called by muse, mutect2, varscan2
- DST | c.1435G>T p.E479* (on ENST00000361203 / NM_001374722.1; = p.E153* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 48/107 reads (45%) | catalogued as COSV99753414; called by muse, mutect2, varscan2
- EHMT2 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV64993781; called by muse, mutect2, varscan2
- EP300 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs773503228, COSV54343542; called by muse, mutect2, varscan2
- EXOC6 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as COSV99591677; called by muse, mutect2, varscan2
- FBXL13 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs370558905, COSV50867489, COSV99978190; called by muse, mutect2, varscan2
- FCGBP | c.5942G>C p.G1981A | Missense Mutation (SNP) | VAF 58/410 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.29); catalogued as COSV55428456, COSV99661675; called by muse, mutect2, varscan2
- GLI3 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101229789; called by muse, mutect2, varscan2
- GLI3 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV101229790; called by muse, mutect2, varscan2
- GOLPH3L | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587718255, COSV99653702; called by muse, mutect2, varscan2
- GSPT2 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100468037; called by muse, mutect2, varscan2
- GTPBP1 | c.1660G>C p.D554H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99323035; called by muse, mutect2, varscan2
- HSF1 | c.531G>C p.Q177H | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101275156; called by muse, mutect2
- IMPG2 | c.1810G>T p.G604W | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99515152; called by muse, mutect2, varscan2
- KRTAP4-2 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs374053955, COSV66658662; called by muse, mutect2, varscan2
- LRP6 | c.55+2T>C p.X19_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV54388531, COSV99742841; called by muse, mutect2
- LRRC36 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as COSV52081727, COSV99338550; called by muse, mutect2, varscan2
- MAN1A1 | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100870341; called by muse, mutect2, varscan2
- MARCHF9 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147077505; called by muse, mutect2, varscan2
- MOV10L1 | c.3272G>C p.G1091A | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99433346; called by muse, mutect2, varscan2
- MPL | c.213G>A p.R71= | Splice Region (SNP) | VAF 32/82 reads (39%) | catalogued as COSV100991446; called by muse, mutect2, varscan2
- MRPS15 | c.521A>C p.N174T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100910615; called by muse, mutect2, varscan2
- MYOCD | c.1388C>G p.S463C | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100590434, COSV58511534; called by muse, mutect2, varscan2
- NEB | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV99418443; called by muse, mutect2, varscan2
- NFATC4 | c.2176C>A p.P726T | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99144919; called by muse, mutect2, varscan2
- NMBR | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99237173, COSV99237256; called by muse, mutect2, varscan2
- OCA2 | c.2374G>A p.V792M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs768651740, COSV100667267, COSV62359262; called by muse, mutect2, varscan2
- OSBP2 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755547940, COSV100212822, COSV100213613; called by mutect2, varscan2
- OSBPL7 | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99136613; called by muse, mutect2
- PCDH18 | c.3372G>T p.E1124D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100787167, COSV61271279; called by muse, mutect2, varscan2
- PIK3C2A | c.4478G>A p.R1493K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99790451; called by muse, mutect2, varscan2
- PIK3CD | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as rs1179481484, COSV100740063; called by muse, mutect2, varscan2
- PLB1 | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs148017311; called by muse, mutect2, varscan2
- PLCB4 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV99594871; called by muse, mutect2, varscan2
- PLCG1 | c.3062C>G p.S1021C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99718676; called by muse, mutect2, varscan2
- PRKDC | c.3733C>T p.R1245W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs200017529; called by muse, mutect2, varscan2
- PSMC6 | c.775G>A p.E259K (on ENST00000612399; = p.E245K on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as COSV101471192; called by muse, mutect2, varscan2
- RAB11FIP2 | c.973T>G p.F325V | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV100843022; called by muse, mutect2
- RAB39A | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100269141; called by muse, mutect2, varscan2
- ROS1 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.486); catalogued as COSV63851586; called by muse, mutect2, varscan2
- RP1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99606849; called by muse, mutect2, varscan2
- RPS6KA6 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV99424447; called by muse, mutect2
- SBF2 | c.4828G>A p.D1610N | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV99813738; called by muse, mutect2, varscan2
- SEC16A | c.2126C>G p.S709* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | catalogued as COSV99257021; called by muse, mutect2
- SGMS1 | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV100693248; called by muse, mutect2, varscan2
- SIRPB1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.561); catalogued as rs368470461; called by muse, mutect2, varscan2
- SLC8A1 | c.1993C>T p.H665Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1381302711, COSV100245396; called by muse, mutect2, varscan2
- SLC8A3 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.228); catalogued as rs1438650441, COSV63519269; called by muse, mutect2, varscan2
- SOGA3 | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100846847; called by muse, mutect2, varscan2
- SPAG17 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs1445468987, COSV100308539; called by muse, mutect2, varscan2
- SPAG4 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV65330961; called by muse, mutect2
- SPEN | c.5607G>C p.K1869N | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101005058, COSV101005088; called by muse, mutect2, varscan2
- SPTBN4 | c.3464C>T p.A1155V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV100150464; called by muse, mutect2, varscan2
- SRP14 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.307); catalogued as rs772340011, COSV99139522; called by muse, mutect2, varscan2
- STRIP2 | c.1883C>A p.S628* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99973628; called by muse, mutect2, varscan2
- TAF1 | c.3463G>C p.E1155Q (on ENST00000373790 / NM_138923.4; = p.E1176Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV99335142; called by muse, mutect2, varscan2
- TATDN1 | c.558G>C p.L186F | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as COSV52678396, COSV99413262; called by muse, mutect2, varscan2
- TENM1 | c.7942G>T p.E2648* | Nonsense Mutation (SNP) | VAF 49/81 reads (60%) | catalogued as COSV100949524; called by muse, mutect2, varscan2
- TEX2 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV99366929; called by muse, mutect2, varscan2
- TRMT61B | c.567C>A p.F189L | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as COSV100066468; called by muse, mutect2, varscan2
- UBE2M | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.703); catalogued as COSV99447931, COSV99448026; called by muse, mutect2, varscan2
- USP53 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs201368952, COSV56794637; called by muse, mutect2, varscan2
- VPS33A | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs766589793, COSV57355984; called by muse, mutect2, varscan2
- YME1L1 | c.1228G>A p.E410K (on ENST00000326799 / NM_139312.3; = p.E353K on NM_014263.4) | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100463464, COSV58758959, COSV58759377; called by muse, mutect2, varscan2
- ZBTB46 | c.275C>G p.S92* | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | catalogued as COSV99828960; called by muse, mutect2, varscan2
- ZKSCAN2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1456185714, COSV100047944; called by muse, mutect2, varscan2
- ZNF45 | c.1919A>G p.Y640C | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99524092; called by muse, mutect2
- ZNF546 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs559273469, COSV61257823; called by muse, mutect2, varscan2
- ZNF699 | c.1913C>T p.T638I | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs772868761, COSV100426897; called by muse, mutect2, varscan2
- ZNF846 | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs370153110; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1341del p.K448Rfs*17 | Frame Shift Del (DEL) | VAF 44/141 reads (31%) | called by mutect2, pindel, varscan2
- AXIN2 | c.540G>A p.S180= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1057521789, COSV61056991; ClinVar: likely benign; called by muse, mutect2, varscan2
- CA8 | c.141A>G p.E47= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100526789; called by muse, mutect2
- CAMSAP1 | c.1674G>A p.E558= | Silent (SNP) | VAF 100/306 reads (33%) | catalogued as rs1441175544, COSV100409714; called by muse, mutect2, varscan2
- CDC25C | c.846G>C p.L282= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100086605; called by muse, mutect2, varscan2
- ERBB3 | c.663C>G p.P221= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as COSV99916310; called by muse, mutect2, varscan2
- GMFB | c.54G>C p.L18= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100794504; called by muse, mutect2, varscan2
- HDAC9 | c.955C>T p.L319= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs1188648308, COSV67779616; called by muse, mutect2, varscan2
- HOXB13 | c.324G>A p.A108= | Silent (SNP) | VAF 75/205 reads (37%) | catalogued as rs768311961, COSV51706554; ClinVar: likely benign; called by muse, mutect2, varscan2
- INTS1 | c.1314G>A p.L438= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV101247666; called by muse, mutect2, varscan2
- JUP | c.945C>T p.L315= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs146804895; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAP2K2 | c.336G>A p.R112= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99502200; called by muse, mutect2, varscan2
- NUDT18 | c.228G>A p.G76= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99248838, COSV99249083; called by muse, mutect2
- OOEP | c.90G>A p.P30= | Silent (SNP) | VAF 89/166 reads (54%) | catalogued as rs748888992, COSV100949804; called by muse, mutect2, varscan2
- PLAU | c.18G>T p.A6= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV101032284; called by muse, mutect2, varscan2
- PPIAL4A | c.117G>C p.L39= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- PPP1R26 | c.1287G>A p.V429= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100778031; called by muse, mutect2, varscan2
- PSMB4 | c.270C>T p.V90= | Silent (SNP) | VAF 40/257 reads (16%) | catalogued as COSV99304904; called by muse, mutect2, varscan2
- SLC46A1 | c.1350C>G p.L450= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99134955; called by muse, mutect2
- SLITRK5 | c.1086C>A p.I362= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100280552, COSV61524717; called by muse, mutect2, varscan2
- SPATA31D1 | c.2391G>C p.L797= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV100782630; called by muse, mutect2, varscan2
- SRRM4 | c.621C>T p.R207= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs763996258, COSV57419505; called by muse, mutect2, varscan2
- TMEM132A | c.1168C>T p.L390= (on ENST00000453848 / NM_178031.3; = p.L391= on NM_017870.4) | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as COSV99134499; called by muse, mutect2, varscan2
- ZNF23 | c.447C>T p.I149= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100612095; called by muse, mutect2, varscan2
- ABL2 | c.158-9592G>A | Intron (SNP) | VAF 35/54 reads (65%) | catalogued as COSV100772601; called by muse, mutect2, varscan2
- ARRDC1 | chr9:137615715 G>C | 3'Flank (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- DST | c.4297-3625_4297-3622dup | Intron (INS) | VAF 11/71 reads (15%) | called by mutect2, pindel
